Somatic mutation profile of tumor specimen TARGET-20-PADYIR-04A (aliquot TARGET-20-PADYIR-04A-02D) from TARGET case TARGET-20-PADYIR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,159 days).
Specimen TARGET-20-PADYIR-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0c032ce-9fca-4049-8b0e-245e32c8686d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PADYIR-14A (Bone Marrow Normal), aliquot TARGET-20-PADYIR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f31a41bd-815b-4718-81fa-cb6038af173d

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Missense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.6313C>T p.L2105F | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752180095, COSV57202666; called by muse, mutect2, varscan2
- TDRD6 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs142991890; called by muse, mutect2, varscan2
- HDAC9 | c.2241G>A p.S747= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs1225877707; called by muse, mutect2, varscan2
- CCDC8 | c.*317C>T | 3'UTR (SNP) | VAF 9/48 reads (19%) | catalogued as rs920812795; called by muse, mutect2, varscan2
- MLLT1 | c.*1491C>T | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- NCAM1 | c.2131+4411C>T | Intron (SNP) | VAF 23/90 reads (26%) | catalogued as rs1183153577; called by muse, mutect2, varscan2
- NF1 | c.*3514G>T | 3'UTR (SNP) | VAF 14/55 reads (25%) | catalogued as rs574282086; called by muse, mutect2, varscan2
- PGM3 | c.*357A>G | 3'UTR (SNP) | VAF 49/141 reads (35%) | catalogued as rs567443060; called by muse, mutect2, varscan2
